Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2CP, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2CP-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Gender: F

HCN:

Ordering

MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Thyroid: LEFT, stitch is superior pole
2. Soft Tissue: Right paratracheal nodes
3. Soft Tissue: Left central paratracheal nodes
4. Thyroid: Right thyroid lobe stitch superior

Date Reported:	6/17/11	

Diagnosis

- 1,4. Multifocal papillary carcinoma, dominant 3.2 cm, follicular variant, left; severe chronic lymphocytic thyroiditis: Thyroid

No pathological diagnosis: Lymph nodes, 4

- Total thyroidectomy specimen.

2. No pathological diagnosis: Lymph nodes, 3 (right paratracheal) dissection specimen

3. No pathological diagnosis: Lymph nodes, 20 (left central paratracheal) dissection specimen

Synoptic Data

Procedure:

Received:

Specimen Integrity:

Specimen Size:

Total thyroidectomy

Fresh

Fragmented

Right lobe:

5.0 cm

2.1 cm

1.3 cm

Left lobe:

5.5 cm

2.4 cm

3.3 cm

Isthmus +/- pyramidal lobe:

2.5 cm

1.0 cm

1CD-0-3

carcinoma, papillary, follicular
variant
8340/3

Site: thyroid, nos C73.9

for 6/18/11

[page 2 of 3]
0.8 cm
Additional specimen: left central paratracheal nodes
4.7 cm
1.8 cm
1.2 cm
Specimen Weight: 34.6 g
Tumor Focality: Multifocal, bilateral
----- DOMINANT TUMOR -----
Tumor Laterality: ~~Left lobe~~
Tumor Size: Greatest dimension: 3.2cm
Additional dimension: 3.0 cm
Additional dimension: 2.2 cm
Histologic Type: ~~Papillary carcinoma, follicular variant~~ *per TSS, follicular variant = 100%*
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Totally encapsulated
Tumor Capsular Invasion: Present, extent widely invasive
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
----- SECOND TUMOR -----
Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 0.8cm
Histologic Type: Papillary carcinoma, follicular variant
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: None
Tumor Capsular Invasion: Not identified
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: m (multiple primary tumors)
Primary Tumor (pT): pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Number of regional lymph nodes examined: 27
Number of regional lymph nodes involved: 0
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Adenomatoid nodule(s) or Nodular follicular disease
Thyroiditis, advanced
Other: multiple additional papillary microcarcinomas identified bilateral.

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

verified by:

Electronically

[page 3 of 3]
Gross Description

1. The specimen labeled with the patient's name and as "thyroid: Left, stitch is superior pole" consists of a lobe of thyroid that is oriented with a stitch. It measures 5.5 cm SI x 3.3 cm ML x 2.4 cm AP and weighs 24.9 g. The external surfaces have fibrous adhesions. One surface nodule measures 0.6 x 0.4 x 0.2 cm. The external surface is painted with liquid bluing. The lobe contains two delineated nodules that measure 1.0 cm SI x 0.8 cm ML x 0.8 cm AP and 3.2 cm SI x 3.0 cm ML x 2.2 cm AP. The remainder of the thyroid tissue is firm, rubbery and pale red-brown. Sections of the larger nodule and non-nodular tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A surface nodule

1B-W lobe, superior to inferior

2. The specimen labeled with the patient's name and as "right paratracheal nodes" consists of two lymph nodes measuring 0.6 x 0.3 x 0.3 cm and 0.7 x 0.5 x 0.3 cm received in 10% buffered formalin.

2A two lymph nodes

3. The specimen labeled with the patient's name and as "left central paratracheal nodes" consists of a piece of fatty tissue measuring 4.7 x 1.8 x 1.2 cm received in 10% buffered formalin. Multiple lymph nodes are identified measuring from 0.2 x 0.2 x 0.2 cm to 1.7 x 0.6 x 0.4 cm in diameter. The specimen is submitted as follows:

3A-C one lymph node bisected, each block.

3D-F multiple lymph nodes, each block.

4. The specimen labeled with the patient's name and as "right thyroid lobe stitch superior" consists of a right hemithyroidectomy specimen that is oriented with a stitch and weighs 9.7 g. The lobe measures 5.0 cm SI x 2.1 cm ML x 1.3 cm AP and the isthmus measures 2.5 SI x 1.0 cm ML x 0.8 cm AP. The external surfaces have fibrous adhesions. One surface nodule measures 0.8 x 0.7 x 0.4 cm. The external surface is painted with liquid bluing. The right lobe contains two delineated nodules that measure 2.0 cm SI x 1.6 cm ML x 1.5 cm AP and 1.0 cm SI x 0.9 cm ML x 0.8 cm AP. The remainder of the thyroid tissue is firm, rubbery and pale red-brown. Sections of both nodules are stored frozen. The remainder of the specimen is submitted as follows:

4A surface nodule

4B-M lobe, superior to inferior

4N,O isthmus

Source: NCI Genomic Data Commons file 8daf3abc-7faf-4edb-b5e2-54d55b24ec97 (TCGA-EM-A2CP.3117EB53-8EAB-40EE-A93C-12EBDC0B45D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).